Somatic mutation profile of tumor specimen ALCH-B2P7-TTP1-A (aliquot ALCH-B2P7-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2P7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.4 years (21,678 days).
Specimen ALCH-B2P7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c659480-3c22-4236-b63e-0c50d72a0b42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2P7-NB1-A (Blood Derived Normal), aliquot ALCH-B2P7-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6229552a-e28b-4ff5-a4e4-94de0393a8ae

The open-access MAF lists 479 somatic variants for this specimen: 319 protein-altering or splice-affecting, 101 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 285, Silent 101, Intron 27, Nonsense Mutation 19, RNA 10, 5'Flank 7, 3'UTR 6, 5'UTR 6, Splice Site 5, Frame Shift Del 4, Splice Region 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FKRP | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as rs886044183, CM1410124, COSV59359617; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 74/272 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.842del p.P281Rfs*6 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 132/398 reads (33%) | hotspot (GDC flag); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; called by muse, mutect2, varscan2
- AC011005.1 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs763418952; called by muse, mutect2, varscan2
- ACKR1 | c.407G>T p.W136L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as CM003678; called by muse, mutect2, varscan2
- ACKR1 | c.408G>T p.W136C | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as CM004832; called by muse, mutect2, varscan2
- ACSM4 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1327721400; called by muse, mutect2, varscan2
- ADAMTSL3 | c.178T>A p.Y60N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV54470685; called by muse, mutect2
- ADGRL3 | c.4174C>A p.Q1392K (on ENST00000506720 / NM_001322402.2; = p.Q1281K on NM_015236.6) | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.036); catalogued as COSV72230275; called by muse, mutect2, varscan2
- ARHGAP6 | c.1449G>C p.R483S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV57303415; called by muse, mutect2, varscan2
- CACNA1S | c.5012G>C p.G1671A | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100755029; called by muse, mutect2, varscan2
- CAGE1 | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.105); catalogued as rs369251036, COSV57082886; called by muse, mutect2
- CATSPER1 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.329); catalogued as rs767156124; called by muse, mutect2, varscan2
- CDK8 | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV67423785; called by muse, varscan2
- CFAP74 | c.4085C>A p.S1362Y | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV69038826; called by muse, mutect2, varscan2
- CHD7 | c.4478G>T p.R1493L | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71106952; called by muse, mutect2
- CLCN4 | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66465446; called by muse, mutect2, varscan2
- CLEC4F | c.101T>A p.I34K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1553397508; called by mutect2, varscan2
- COL6A5 | c.4504C>G p.P1502A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs1263088427; called by muse, mutect2, varscan2
- CSMD2 | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV99596547; called by muse, mutect2, varscan2
- DCDC1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 113/481 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs760267107; called by muse, mutect2, varscan2
- DCSTAMP | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV52576267, COSV99034292; called by muse, mutect2, varscan2
- DEFB112 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 51/287 reads (18%) | catalogued as rs776634689, COSV59182974; called by muse, mutect2, varscan2
- DENND1C | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV67375499; called by muse, mutect2, varscan2
- DIP2C | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1478446925; called by muse, mutect2, varscan2
- DMD | c.4000G>A p.G1334R | Missense Mutation (SNP) | VAF 82/397 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs146880270, COSV63780212; called by muse, mutect2, varscan2
- DNAH17 | c.2439G>C p.E813D | Missense Mutation (SNP) | VAF 54/404 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV101101934; called by muse, mutect2, varscan2
- DNAH3 | c.8945C>A p.T2982N | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as rs754790201; called by muse, mutect2, varscan2
- DRAXIN | c.1005G>C p.E335D | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.39); catalogued as rs771879554; called by muse, mutect2, varscan2
- EFCAB1 | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs1320624675; called by muse, varscan2
- EXO1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs751977225; called by muse, mutect2, varscan2
- F12 | c.1156T>A p.Y386N | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99499850; called by muse, mutect2, varscan2
- F8 | c.1619C>A p.P540Q | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD111369, CM088394; called by muse, mutect2, varscan2
- FAT1 | c.8416A>T p.S2806C | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV71676644; called by muse, mutect2, varscan2
- FSCB | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs201253705; called by muse, mutect2, varscan2
- GFRA1 | c.396C>A p.F132L | Missense Mutation (SNP) | VAF 68/424 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1403809567, COSV100815704, COSV62609152; called by muse, varscan2
- GLUD2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs369810909, COSV60153302; called by muse, mutect2, varscan2
- GRIA2 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 26/475 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV52385291; called by muse, mutect2
- GRIN2A | c.964G>C p.G322R | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV100409746; called by muse, mutect2, varscan2
- GRM7 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV63153164; called by muse, mutect2, varscan2
- GRM7 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63137735; called by muse, varscan2
- HAS1 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV55785948; called by muse, mutect2, varscan2
- HCFC1 | c.5406C>A p.S1802R | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1557112418; called by muse, mutect2
- HCN4 | c.2995C>T p.R999W | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs538668505, COSV56086382; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXC10 | c.504C>A p.N168K | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs1315773554; called by muse, mutect2, varscan2
- HSD3B2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as CM970746, COSV101027541; called by muse, mutect2, varscan2
- IFNA4 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs138903890; called by mutect2, varscan2
- INA | c.1486A>G p.S496G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.124); catalogued as COSV63975968; called by muse, mutect2
- ITGA3 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs774498970; called by muse, mutect2, varscan2
- ITGAD | c.1484C>A p.P495H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66758245; called by muse, mutect2, varscan2
- ITIH1 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs892554181; called by muse, mutect2
- KCNH5 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100527574; called by muse, mutect2, varscan2
- KCNK16 | c.663C>A p.G221= | Splice Region (SNP) | VAF 40/102 reads (39%) | catalogued as COSV100949142; called by muse, varscan2
- KEL | c.1633G>T p.V545L | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs549070520; called by muse, varscan2
- KLHL30 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as rs1007756444; called by muse, mutect2, varscan2
- KLK6 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59566861; called by muse, mutect2, varscan2
- KRTAP11-1 | c.308del p.P103Rfs*94 | Frame Shift Del (DEL) | VAF 50/230 reads (22%) | catalogued as COSV60094064; called by mutect2, pindel, varscan2
- LANCL3 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1556430612; called by muse, mutect2, varscan2
- LCE2D | c.90dup p.K31Qfs*63 | Frame Shift Ins (INS) | VAF 50/241 reads (21%) | catalogued as rs762629502; called by mutect2, pindel, varscan2
- LDOC1 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 114/674 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782148167, COSV100983225; called by muse, mutect2, varscan2
- LY6K | c.211del p.A71Pfs*2 | Frame Shift Del (DEL) | VAF 69/392 reads (18%) | catalogued as COSV52833261; called by mutect2, pindel, varscan2
- MAGEC3 | c.1168A>G p.S390G | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.152); catalogued as rs773915462; called by muse, mutect2, varscan2
- MAML1 | c.593T>A p.L198* | Nonsense Mutation (SNP) | VAF 48/203 reads (24%) | catalogued as COSV99483342; called by muse, mutect2, varscan2
- MAP11 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs1295333762, COSV57585766; called by muse, mutect2, varscan2
- MARK1 | c.21G>C p.L7F | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs910325250; called by muse, mutect2, varscan2
- MARK2 | c.980G>C p.R327P | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV59280888; called by muse, mutect2, varscan2
- MARK2 | c.1691G>A p.R564H (on ENST00000402010 / NM_001039469.2; = p.R509H on NM_004954.5) | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs751564327; called by mutect2, varscan2
- MDGA2 | c.2006G>A p.S669N (on ENST00000399232 / NM_001113498.2; = p.S371N on NM_182830.4) | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV62096296; called by muse, varscan2
- MEX3C | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as rs759565342; called by muse, mutect2, varscan2
- MGAM | c.1166C>A p.T389N | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs781964893, COSV101527414; called by muse, mutect2, varscan2
- MMP9 | c.1406C>A p.P469H | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV63433830; called by muse, mutect2, varscan2
- MON1B | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50248906; called by muse, varscan2
- MUC17 | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV60291466; called by mutect2, varscan2
- MYH15 | c.2633C>A p.S878* | Nonsense Mutation (SNP) | VAF 35/288 reads (12%) | catalogued as COSV56305714; called by muse, mutect2, varscan2
- MYO1H | c.723C>A p.D241E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as rs990957954; called by muse, mutect2, varscan2
- MYT1L | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs565377413; called by muse, mutect2, varscan2
- NEBL | c.947A>G p.H316R | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101009365; called by muse, mutect2, varscan2
- NEFL | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753906952; called by muse, mutect2, varscan2
- NEK1 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 22/314 reads (7%) | catalogued as COSV71458404; called by muse, mutect2
- NLGN3 | c.2468C>A p.T823K (on ENST00000358741 / NM_181303.2; = p.T803K on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/494 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV62441404; called by muse, mutect2, varscan2
- NLRP13 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs1477828825, COSV61622823; called by muse, mutect2, varscan2
- NLRP14 | c.1320C>A p.Y440* | Nonsense Mutation (SNP) | VAF 100/360 reads (28%) | catalogued as rs145713104, COSV100205217, COSV55071245; called by muse, varscan2
- NOL6 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as rs780801923, COSV99954970; called by muse, mutect2, varscan2
- NOTCH4 | c.4189C>A p.P1397T | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV66685490; called by muse, varscan2
- NOXRED1 | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV53627589; called by muse, mutect2, varscan2
- OR2M3 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV101513415; called by muse, mutect2, varscan2
- OVCH1 | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.783); catalogued as COSV58960925; called by muse, varscan2
- PARP4 | c.2225C>T p.T742I | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV67964518; called by muse, mutect2
- PEAR1 | c.2687A>G p.N896S | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV52772326; called by muse, mutect2
- PGK1 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs782378406; called by muse, varscan2
- PHLDB2 | c.3459G>T p.M1153I (on ENST00000393925 / NM_001134439.2; = p.M1110I on NM_145753.2) | Missense Mutation (SNP) | VAF 68/380 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV67311642; called by muse, varscan2
- POTEJ | c.2317C>A p.L773M | Missense Mutation (SNP) | VAF 110/537 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.285); catalogued as rs1558936564, COSV68641544; called by muse, mutect2, varscan2
- PPP4R3C | c.2177C>A p.T726K | Missense Mutation (SNP) | VAF 71/423 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV69080742; called by muse, mutect2, varscan2
- PXDN | c.1837G>T p.V613F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV53244931; called by muse, mutect2, varscan2
- REG1A | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV52068898, COSV52071880; called by muse, mutect2, varscan2
- RETREG1 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100104764; called by muse, varscan2
- RPL10L | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs764186971, COSV100022301; called by muse, mutect2, varscan2
- RPS6KA1 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1372143465; called by muse, mutect2
- RXFP3 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs746298276; called by muse, mutect2, varscan2
- RXFP3 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as rs772356729; called by muse, mutect2, varscan2
- RYR2 | c.3986G>T p.G1329V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63689800; called by muse, varscan2
- RYR3 | c.7363C>A p.R2455S (on ENST00000389232; = p.R2456S on NM_001036.6) | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs770600412, COSV66801408; called by muse, mutect2, varscan2
- SLITRK1 | c.971C>A p.A324E | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.081); catalogued as COSV101000028; called by muse, varscan2
- SLITRK6 | c.1557G>T p.W519C | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68391275; called by muse, varscan2
- SPEG | c.8573C>T p.A2858V | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs779078554, COSV56676583; called by muse, mutect2, varscan2
- STYK1 | c.1194G>T p.L398F | Missense Mutation (SNP) | VAF 11/328 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.896); catalogued as rs967812609; called by muse, mutect2
- SUV39H1 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as COSV61921488; called by muse, mutect2, varscan2
- TBX5 | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV59861243; called by muse, mutect2, varscan2
- TENM4 | c.8215G>T p.G2739C | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370869672; called by muse, mutect2, varscan2
- TFAP2D | c.384C>A p.D128E | Missense Mutation (SNP) | VAF 124/434 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV50449879; called by muse, mutect2, varscan2
- TGFB2 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV65109777; called by muse, varscan2
- THSD7A | c.4545G>C p.R1515S | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs1195774857; called by muse, mutect2, varscan2
- TMEM270 | c.731C>A p.S244* | Nonsense Mutation (SNP) | VAF 39/210 reads (19%) | catalogued as COSV57638971; called by muse, varscan2
- TOP3B | c.1099-2A>T p.X367_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV64116653; called by muse, mutect2
- TRIM58 | c.649del p.E217Rfs*13 | Frame Shift Del (DEL) | VAF 122/484 reads (25%) | catalogued as COSV100825156; called by mutect2, pindel, varscan2
- UNC13D | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs750548504; called by muse, mutect2
- VSTM2A | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 35/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs775572838; called by muse, mutect2
- WT1 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as rs1565001804; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZDHHC11 | c.976T>C p.C326R | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as rs778944068; called by muse, mutect2
- ZFHX4 | c.7415C>A p.S2472Y | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV99255008; called by muse, mutect2, varscan2
- ZNF536 | c.2517G>T p.R839S | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100835786, COSV62824416; called by muse, mutect2, varscan2
- ZNF804B | c.629T>A p.L210H | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.635); catalogued as rs1230164278; called by muse, mutect2, varscan2
- ABCD1 | c.1373A>T p.E458V | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ADAM19 | c.2815C>A p.L939I | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAM23 | c.1937G>T p.R646L | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ADAMTS16 | c.2931C>A p.S977R | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AGMO | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- AKAP6 | c.5289G>T p.L1763F | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMPD1 | c.1618A>T p.T540S | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.714); called by muse, varscan2
- ANKMY1 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 40/550 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ARHGEF15 | c.1969C>G p.P657A | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ARL6 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, varscan2
- ARRB2 | c.255C>G p.Y85* | Nonsense Mutation (SNP) | VAF 80/237 reads (34%) | called by muse, mutect2, varscan2
- ASB11 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ASTN2 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.066); called by muse, varscan2
- AXL | c.1628G>T p.G543V (on ENST00000301178 / NM_021913.5; = p.G534V on NM_001699.6) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BHMG1 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- BMS1 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 50/272 reads (18%) | called by muse, varscan2
- CABP1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CBLN2 | c.61dup p.A21Gfs*109 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | called by mutect2, pindel
- CCNJL | c.1099G>T p.G367W | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CES5A | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, varscan2
- CFP | c.596G>T p.W199L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CGB1 | c.390C>G p.D130E | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CHRD | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNB2 | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIART | c.156G>T p.R52S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CIDEA | c.551C>A p.T184K | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CLEC4M | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP4 | c.3602G>T p.S1201I | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CPA5 | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CPO | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CREB3L3 | c.633G>T p.Q211H | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CSMD2 | c.3437C>A p.S1146Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CSMD3 | c.10055G>C p.C3352S (on ENST00000297405 / NM_001363185.1; = p.C3183S on NM_052900.3) | Missense Mutation (SNP) | VAF 91/487 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CUL9 | c.5268G>T p.W1756C | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUX2 | c.404G>T p.W135L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CUX2 | c.405G>T p.W135C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DBX1 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DCDC1 | c.5312C>A p.P1771Q (on ENST00000597505 / NM_001367979.1; = p.P878Q on NM_020869.3) | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.114); called by muse, mutect2
- DCLK1 | c.1493C>A p.A498D | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- DDX60 | c.2968G>C p.V990L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, varscan2
- DGAT2 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.2044T>A p.F682I | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- DOCK8 | c.3076G>A p.V1026M | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.184); called by muse, varscan2
- EBF3 | c.798G>T p.K266N (on ENST00000355311 / NM_001375392.1; = p.K257N on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EP400 | c.9256G>C p.A3086P | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA10 | c.380A>T p.N127I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPN2 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESX1 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 118/588 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- F9 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FAM220A | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 21/389 reads (5%) | called by muse, mutect2
- FAM47C | c.2143C>A p.H715N | Missense Mutation (SNP) | VAF 75/486 reads (15%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- FBXO24 | c.962dup p.V322Sfs*4 (on ENST00000241071 / NM_033506.3; = p.V360Sfs*4 on NM_012172.5) | Frame Shift Ins (INS) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- FLG | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FRY | c.1485G>T p.M495I | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- FUOM | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBP1 | c.1471+3G>T | Splice Region (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- GCN1 | c.6572G>T p.R2191L | Missense Mutation (SNP) | VAF 111/473 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- GJA1 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGA6L6 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 49/619 reads (8%) | called by muse, mutect2, varscan2
- GREM2 | c.141C>A p.H47Q | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK2 | c.1226G>T p.S409I | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2
- GRIPAP1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- GRPR | c.1115G>C p.S372T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HEXA | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HMGN5 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- HOXA5 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.242); called by mutect2, varscan2
- HUWE1 | c.11614G>T p.D3872Y | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- HYDIN | c.2010G>C p.E670D | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- IGKV1-9 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 136/511 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- IGSF22 | c.1704C>A p.H568Q | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IL12RB2 | c.2247C>A p.S749R | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ISOC1 | c.62C>G p.A21G | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2
- ITGA3 | c.1759G>T p.G587W | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNA4 | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- KCNC2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCND2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH3 | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 80/531 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNN1 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, varscan2
- KIAA1328 | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.013); called by muse, mutect2
- KIF26A | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 104/322 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KIF4A | c.2512C>A p.Q838K | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- KIT | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KLC1 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, varscan2
- KLHL34 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KMO | c.1313C>A p.T438N | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, varscan2
- LACC1 | c.573A>G p.I191M | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2
- LAMA2 | c.7667C>A p.T2556N | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCK | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGR5 | c.598C>A p.H200N | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, varscan2
- LILRA2 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 90/381 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- LINC02871 | n.920+1G>A | Splice Site (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- LRP1 | c.3515G>T p.C1172F | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC7 | c.2674G>C p.D892H (on ENST00000651989 / NM_001370785.2; = p.D859H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRD1 | c.2102A>T p.Q701L | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- LRRFIP1 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LTK | c.2243G>C p.C748S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MADD | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- MAMLD1 | c.1021C>A p.R341S | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- MAP2K5 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, varscan2
- MCM9 | c.2294C>A p.P765H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- MICALL2 | c.642-1G>T p.X214_splice | Splice Site (SNP) | VAF 74/174 reads (43%) | called by muse, mutect2, varscan2
- MSLNL | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- MUC5B | c.9812C>A p.P3271Q | Missense Mutation (SNP) | VAF 106/701 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYH7 | c.4279G>A p.D1427N | Missense Mutation (SNP) | VAF 115/547 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCBP2 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NLGN3 | c.1681T>C p.W561R (on ENST00000358741 / NM_181303.2; = p.W541R on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN4X | c.2371C>A p.P791T | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP14 | c.1186A>T p.T396S | Missense Mutation (SNP) | VAF 121/446 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, varscan2
- NLRP5 | c.1615G>T p.V539L | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NMRK2 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NTRK1 | c.1010C>A p.A337D | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OBSCN | c.5026G>T p.A1676S | Missense Mutation (SNP) | VAF 62/524 reads (12%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- OLIG3 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G7 | c.460C>A p.H154N | Missense Mutation (SNP) | VAF 66/336 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, varscan2
- OR14A16 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2
- OR2L3 | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- OR2W3 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR4A16 | c.900G>T p.W300C | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OR4D10 | c.565C>A p.H189N | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- OR4N2 | c.581T>A p.V194E | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- OR5H2 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR5H2 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR5T2 | c.413C>A p.A138E | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, varscan2
- PAMR1 | c.2006C>A p.A669E (on ENST00000619888 / NM_001001991.3; = p.A686E on NM_015430.4) | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PAX1 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PCDHB9 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- PIK3AP1 | c.198T>G p.C66W | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PKD1 | c.7558G>T p.G2520C | Missense Mutation (SNP) | VAF 57/421 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PLPPR4 | c.1300A>G p.S434G | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- POLR1B | c.2446G>A p.G816R | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- POU3F1 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, varscan2
- PRKG1 | c.775A>T p.N259Y | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKG2 | c.1962C>A p.D654E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, varscan2
- PTPRC | c.1171+1G>T p.X391_splice | Splice Site (SNP) | VAF 24/134 reads (18%) | called by muse, varscan2
- REST | c.3073G>T p.E1025* | Nonsense Mutation (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- RGPD4 | c.3501C>G p.C1167W | Missense Mutation (SNP) | VAF 177/368 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS12 | c.586A>T p.K196* | Nonsense Mutation (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- RNF152 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); called by muse, mutect2
- ROPN1L | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL1 | c.1544A>C p.E515A | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SHLD2 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by mutect2, varscan2
- SIGLEC7 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 57/431 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC24A5 | c.185A>T p.Q62L | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- SLC35A2 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC43A1 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 142/514 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SLC8A1 | c.2491C>A p.L831M | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO1B3 | c.1051A>G p.S351G | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SLITRK5 | c.1549C>A p.L517M | Missense Mutation (SNP) | VAF 89/384 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- STX7 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, varscan2
- SYN1 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- SYNPO2 | c.1172C>A p.S391Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SYT9 | c.936G>T p.R312S | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYTL4 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TBC1D8B | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- TBXT | c.209G>T p.R70M | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TDP1 | c.884+8G>T | Splice Region (SNP) | VAF 55/324 reads (17%) | called by muse, varscan2
- TECTA | c.5510G>T p.C1837F | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TEX11 | c.1034T>A p.L345Q (on ENST00000344304; = p.L330Q on NM_031276.3) | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TLN2 | c.3405G>T p.Q1135H | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TMLHE | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, varscan2
- TMPRSS5 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 15/285 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRAV14DV4 | c.243A>T p.E81D | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRHDE | c.1916G>T p.W639L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRPC4 | c.1567T>A p.Y523N | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TTBK1 | c.380C>A p.T127K | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TTN | c.96087T>A p.C32029* (on ENST00000591111; = p.C24605* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- UACA | c.3760T>A p.Y1254N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); called by muse, varscan2
- UBAP2 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- UNC80 | c.4691A>T p.Q1564L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, varscan2
- USH2A | c.14168G>T p.S4723I | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- USH2A | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- VIT | c.1246C>A p.L416I (on ENST00000389975 / NM_001177969.1; = p.L431I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- VSX2 | c.1055T>A p.L352H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- WDPCP | c.1930T>A p.L644M | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- WDR25 | c.1181G>T p.S394I | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WNK3 | c.2435G>T p.G812V | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- WSB1 | c.868A>T p.I290F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.033); called by muse, mutect2
- XPNPEP1 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- YARS1 | c.204+1del p.X68_splice | Splice Site (DEL) | VAF 48/239 reads (20%) | called by mutect2, pindel, varscan2
- YME1L1 | c.1355T>C p.M452T (on ENST00000326799 / NM_139312.3; = p.M395T on NM_014263.4) | Missense Mutation (SNP) | VAF 67/289 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- YME1L1 | c.1021G>T p.V341F (on ENST00000326799 / NM_139312.3; = p.V284F on NM_014263.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB2 | c.1342T>A p.Y448N | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB41 | c.1188G>C p.Q396H | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZDHHC9 | c.368C>A p.P123Q | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFHX3 | c.2360G>T p.S787I | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); called by muse, varscan2
- ZMYM3 | c.2114A>T p.D705V | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZNF16 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF275 | c.1159C>A p.R387S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF441 | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF536 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 96/446 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF536 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 57/354 reads (16%) | called by muse, mutect2, varscan2
- ZNF549 | c.1175G>T p.S392I (on ENST00000376233 / NM_001199295.2; = p.S379I on NM_153263.2) | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ZNF674 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.165); called by muse, mutect2
- ZNF684 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF746 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, varscan2
- ZNF746 | c.1626G>T p.E542D | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.046); called by muse, varscan2
- ABCA4 | c.6210G>T p.T2070= | Silent (SNP) | VAF 84/489 reads (17%) | catalogued as rs1368610622, COSV100933135, COSV64675196; called by muse, mutect2, varscan2
- ABCA4 | c.4918C>A p.R1640= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as CM983728; called by muse, varscan2
- ACAP2 | c.1932A>T p.P644= | Silent (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2
- ACVRL1 | c.831G>T p.T277= | Silent (SNP) | VAF 39/230 reads (17%) | catalogued as COSV101187752, COSV66361479; called by muse, mutect2, varscan2
- ADAM21 | c.726G>T p.V242= | Silent (SNP) | VAF 44/203 reads (22%) | catalogued as COSV99961388; called by muse, mutect2, varscan2
- ADGRD2 | c.2586C>A p.A862= | Silent (SNP) | VAF 51/252 reads (20%) | catalogued as rs771873677; called by muse, mutect2, varscan2
- AHNAK2 | c.5664C>T p.D1888= | Silent (SNP) | VAF 90/542 reads (17%) | catalogued as rs573354991; called by muse, mutect2, varscan2
- AMER1 | c.318T>A p.P106= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, varscan2
- ANGPT4 | c.279A>C p.A93= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- APOB | c.2313G>A p.P771= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs552986140; ClinVar: likely benign; called by muse, mutect2, varscan2
- BACH2 | c.931C>A p.R311= | Silent (SNP) | VAF 35/247 reads (14%) | called by muse, mutect2, varscan2
- BOC | c.1449C>G p.T483= | Silent (SNP) | VAF 25/192 reads (13%) | called by muse, mutect2, varscan2
- CACNA1B | c.3261T>A p.P1087= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- CALML5 | c.54C>T p.S18= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as rs377606833; called by muse, mutect2, varscan2
- CAPG | c.924A>T p.A308= | Silent (SNP) | VAF 20/346 reads (6%) | called by muse, mutect2
- CAPG | c.228C>A p.A76= | Silent (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- CARMIL1 | c.3630G>C p.G1210= | Silent (SNP) | VAF 24/146 reads (16%) | called by muse, varscan2
- CASR | c.2091C>G p.G697= (on ENST00000490131; = p.G774= on NM_000388.4) | Silent (SNP) | VAF 88/461 reads (19%) | called by muse, mutect2, varscan2
- CATSPER1 | c.105C>A p.G35= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- CCDC144A | c.2944C>T p.L982= | Silent (SNP) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- CCDC73 | c.2619A>T p.P873= | Silent (SNP) | VAF 14/241 reads (6%) | called by muse, mutect2
- CCSER2 | c.999T>A p.T333= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, varscan2
- CDK5 | c.655C>T p.L219= | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- CDK5 | c.654G>T p.L218= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- CELF4 | c.849C>A p.G283= | Silent (SNP) | VAF 58/218 reads (27%) | called by muse, mutect2, varscan2
- CENPV | c.267G>A p.P89= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1359213677; called by mutect2, varscan2
- CFAP43 | c.711A>T p.V237= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.1152C>A p.P384= | Silent (SNP) | VAF 28/264 reads (11%) | catalogued as rs967697335, COSV70488635, COSV70505169, COSV70510848; called by muse, mutect2
- COL6A3 | c.5148C>T p.H1716= | Silent (SNP) | VAF 76/340 reads (22%) | catalogued as rs114845780, COSV55098400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACD | c.438C>A p.P146= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs1560532696; called by muse, mutect2, varscan2
- CYP2A13 | c.1041C>A p.A347= | Silent (SNP) | VAF 25/168 reads (15%) | called by muse, mutect2, varscan2
- DISP3 | c.2703C>A p.R901= | Silent (SNP) | VAF 51/332 reads (15%) | called by muse, varscan2
- DOCK2 | c.1551G>A p.L517= | Silent (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- DPPA3 | c.99C>T p.S33= | Silent (SNP) | VAF 34/173 reads (20%) | called by muse, mutect2, varscan2
- EPHA3 | c.1233C>A p.A411= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV60694979; called by muse, mutect2, varscan2
- FOXN4 | c.1194C>T p.P398= | Silent (SNP) | VAF 40/191 reads (21%) | catalogued as rs372728344; called by muse, mutect2, varscan2
- GAD2 | c.165G>A p.P55= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as rs763695378, COSV52156971; called by muse, mutect2, varscan2
- GATC | c.201A>G p.L67= | Silent (SNP) | VAF 23/183 reads (13%) | called by muse, mutect2, varscan2
- GLUD2 | c.48C>G p.P16= | Silent (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- GRID1 | c.2973C>G p.P991= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- GRIN3B | c.1584G>A p.A528= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs62131161; called by muse, mutect2, varscan2
- GUCA1C | c.102G>T p.L34= | Silent (SNP) | VAF 26/180 reads (14%) | called by muse, varscan2
- HECW1 | c.4461C>A p.T1487= | Silent (SNP) | VAF 73/230 reads (32%) | called by muse, mutect2, varscan2
- HSPA6 | c.258G>A p.Q86= | Silent (SNP) | VAF 94/408 reads (23%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.126C>T p.T42= | Silent (SNP) | VAF 27/441 reads (6%) | called by muse, mutect2
- KCND1 | c.384C>A p.V128= | Silent (SNP) | VAF 74/551 reads (13%) | catalogued as COSV99501745; called by muse, mutect2, varscan2
- KCNQ2 | c.546G>T p.V182= | Silent (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- KERA | c.372C>G p.L124= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs1012984743; called by muse, mutect2, varscan2
- KIAA1210 | c.3114A>T p.T1038= | Silent (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- LILRB1 | c.1194A>C p.A398= (on ENST00000427581; = p.A362= on NM_006669.6) | Silent (SNP) | VAF 64/711 reads (9%) | called by muse, mutect2
- LIPI | c.702C>A p.S234= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as COSV100753676; called by muse, mutect2, varscan2
- LMX1A | c.873G>T p.T291= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs200784612, COSV54222957; called by muse, mutect2
- LONP1 | c.492C>T p.V164= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs768872818, COSV100638583; called by muse, mutect2, varscan2
- LRIT2 | c.459G>T p.L153= | Silent (SNP) | VAF 60/265 reads (23%) | called by muse, mutect2, varscan2
- MSRB2 | c.66G>T p.R22= | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1185G>C p.L395= | Silent (SNP) | VAF 61/191 reads (32%) | called by muse, varscan2
- NHLRC3 | c.624A>T p.T208= | Silent (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- NR0B1 | c.730C>A p.R244= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV66764407; called by muse, mutect2, varscan2
- OAS3 | c.1755G>A p.E585= | Silent (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- OR10G4 | c.240G>T p.L80= | Silent (SNP) | VAF 18/141 reads (13%) | called by muse, varscan2
- OR10J1 | c.273C>A p.P91= | Silent (SNP) | VAF 55/196 reads (28%) | catalogued as COSV71128282; called by muse, mutect2, varscan2
- OR2AJ1 | c.804A>T p.P268= | Silent (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- OR2M7 | c.894C>A p.T298= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- OR4D10 | c.564C>A p.A188= | Silent (SNP) | VAF 26/178 reads (15%) | called by muse, varscan2
- OR52A5 | c.210C>A p.A70= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1415136044; called by muse, mutect2, varscan2
- OR52L1 | c.648T>C p.Y216= | Silent (SNP) | VAF 24/186 reads (13%) | called by muse, varscan2
- OR5A1 | c.489C>A p.A163= | Silent (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- OR9Q1 | c.675C>A p.I225= | Silent (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- P2RY8 | c.171G>T p.P57= | Silent (SNP) | VAF 56/259 reads (22%) | called by muse, mutect2, varscan2
- PCDHA13 | c.2082G>T p.V694= | Silent (SNP) | VAF 99/319 reads (31%) | called by muse, mutect2, varscan2
- PGAM4 | c.6C>A p.A2= | Silent (SNP) | VAF 45/215 reads (21%) | called by muse, mutect2, varscan2
- PLXNA4 | c.2868C>G p.L956= | Silent (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- PPP2R2C | c.645G>A p.P215= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs1278611264, COSV58671634; called by muse, mutect2
- PPRC1 | c.501G>C p.L167= | Silent (SNP) | VAF 53/229 reads (23%) | called by muse, mutect2, varscan2
- ROBO2 | c.927C>T p.T309= | Silent (SNP) | VAF 64/356 reads (18%) | catalogued as rs756562291, COSV59930458, COSV59934473; called by muse, mutect2, varscan2
- RPS4X | c.285G>T p.T95= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs777399014; called by muse, mutect2, varscan2
- RYR2 | c.5754C>A p.V1918= | Silent (SNP) | VAF 22/122 reads (18%) | called by muse, varscan2
- SCN3A | c.1395A>G p.A465= | Silent (SNP) | VAF 51/176 reads (29%) | catalogued as rs752125391; called by muse, mutect2, varscan2
- SIRPB1 | c.1149G>T p.L383= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as rs772159985, COSV99498581; called by muse, varscan2
- SPRY3 | c.267C>A p.S89= | Silent (SNP) | VAF 89/529 reads (17%) | called by muse, mutect2, varscan2
- ST18 | c.888G>T p.L296= | Silent (SNP) | VAF 75/352 reads (21%) | catalogued as COSV99387572; called by muse, mutect2, varscan2
- STK32B | c.1156C>A p.R386= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs758344233; called by muse, mutect2, varscan2
- STRADB | c.330A>T p.L110= | Silent (SNP) | VAF 40/241 reads (17%) | called by muse, mutect2, varscan2
- TBC1D14 | c.78C>T p.P26= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- TDRD6 | c.765C>T p.V255= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- TEAD4 | c.135G>A p.P45= | Silent (SNP) | VAF 33/237 reads (14%) | catalogued as rs767498795, COSV63280372; called by muse, mutect2, varscan2
- TEX13C | c.2280C>A p.P760= | Silent (SNP) | VAF 44/258 reads (17%) | called by muse, mutect2, varscan2
- TFE3 | c.711C>G p.T237= | Silent (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- TGM2 | c.1524G>T p.L508= | Silent (SNP) | VAF 43/409 reads (11%) | called by muse, mutect2, varscan2
- TNFRSF18 | c.690A>T p.A230= | Silent (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2
- TNXB | c.10539G>T p.G3513= (on ENST00000647633; = p.G3266= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- TRIM28 | c.18G>T p.A6= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- TRIM64B | c.696G>T p.L232= | Silent (SNP) | VAF 35/343 reads (10%) | called by muse, mutect2, varscan2
- TRIM9 | c.1399C>T p.L467= | Silent (SNP) | VAF 35/280 reads (13%) | catalogued as COSV53615248; called by muse, mutect2, varscan2
- VCAM1 | c.1590G>T p.V530= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV104399173; called by muse, mutect2, varscan2
- VIP | c.387C>A p.V129= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV65888685; called by muse, mutect2
- WNT9B | c.30C>A p.A10= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7416C>A p.S2472= | Silent (SNP) | VAF 32/222 reads (14%) | called by muse, mutect2, varscan2
- ZNF469 | c.6114G>T p.L2038= (on ENST00000437464; = p.L2066= on NM_001367624.2) | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- ZNF721 | c.1206G>A p.E402= (on ENST00000338977; = p.E414= on NM_133474.4) | Silent (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- ZNF860 | c.1155T>G p.L385= | Silent (SNP) | VAF 28/85 reads (33%) | called by muse, varscan2
- AC107023.1 | n.25+7185T>A | Intron (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- AC136759.1 | n.618C>G | RNA (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- ACP4 | chr19:50798253 C>A | 3'Flank (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- ADGRB2 | c.3353+19A>T | Intron (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826515 T>A | 3'Flank (SNP) | VAF 46/337 reads (14%) | called by muse, varscan2
- AL353804.7 | chrX:73849797 C>A | 5'Flank (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
- AL450442.1 | n.724del | RNA (DEL) | VAF 34/216 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF4 | chr2:130915139 C>T | 5'Flank (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- CARD6 | chr5:40860050 G>A | 3'Flank (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- CD1C | c.*105C>A | 3'UTR (SNP) | VAF 12/158 reads (8%) | catalogued as rs1368763557, COSV63805632; called by muse, mutect2
- CDK16 | c.-6-377G>T | Intron (SNP) | VAF 40/282 reads (14%) | called by muse, mutect2, varscan2
- CIDEA | c.38+292A>G | Intron (SNP) | VAF 39/192 reads (20%) | called by muse, mutect2, varscan2
- COL4A2 | c.1433-634C>A | Intron (SNP) | VAF 48/194 reads (25%) | called by muse, mutect2, varscan2
- CSMD3 | c.7885+82T>A | Intron (SNP) | VAF 12/100 reads (12%) | called by mutect2, varscan2
- EARS2 | c.296-1707T>A | Intron (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- EDN3 | c.-45G>A | 5'UTR (SNP) | VAF 57/221 reads (26%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009907 G>T | 5'Flank (SNP) | VAF 11/67 reads (16%) | catalogued as rs535498729; called by muse, mutect2, varscan2
- FKBP9P1 | chr7:55691448 G>C | 5'Flank (SNP) | VAF 38/122 reads (31%) | called by muse, varscan2
- HBE1 | c.-267+36847G>T | Intron (SNP) | VAF 14/199 reads (7%) | called by muse, mutect2
- HYDIN | c.-23-16902T>A | Intron (SNP) | VAF 5/100 reads (5%) | catalogued as rs1307561024; called by muse, mutect2
- IL7R | c.801-23C>T | Intron (SNP) | VAF 17/237 reads (7%) | catalogued as rs921143502; called by muse, mutect2
- LINC00692 | n.621A>T | RNA (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- LYRM7 | c.-37G>T | 5'UTR (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- MDGA2 | c.2752+1521G>T | Intron (SNP) | VAF 21/211 reads (10%) | catalogued as COSV62094871; called by muse, mutect2, varscan2
- METTL2B | c.*721A>G | 3'UTR (SNP) | VAF 12/146 reads (8%) | catalogued as rs1386784188, COSV52310130; called by muse, mutect2
- MIP | c.606+26C>A | Intron (SNP) | VAF 19/295 reads (6%) | called by muse, mutect2
- MIR124-2HG | n.262C>A | RNA (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- MYL7 | c.194-26del | Intron (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- NBPF7 | n.982C>G | RNA (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.255C>A | RNA (SNP) | VAF 56/606 reads (9%) | called by muse, mutect2
- NRG3 | c.824-125970A>G | Intron (SNP) | VAF 23/175 reads (13%) | catalogued as rs1162029500; called by muse, mutect2, varscan2
- NRP1 | c.981+4571del | Intron (DEL) | VAF 16/161 reads (10%) | called by mutect2, pindel*
- NUBP1 | chr16:10743820 C>A | 5'Flank (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- OPRM1 | c.-267G>T | 5'UTR (SNP) | VAF 16/62 reads (26%) | catalogued as COSV57687887; called by muse, mutect2, varscan2
- OR4C4P | n.689C>A | RNA (SNP) | VAF 70/236 reads (30%) | called by muse, mutect2, varscan2
- OSCAR | c.*359C>A | 3'UTR (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- PAQR5 | c.512+1832G>T | Intron (SNP) | VAF 18/104 reads (17%) | called by muse, varscan2
- PARVG | c.144+737G>T | Intron (SNP) | VAF 71/263 reads (27%) | called by muse, mutect2, varscan2
- PCF11 | c.4453-21A>T | Intron (SNP) | VAF 32/187 reads (17%) | called by muse, mutect2, varscan2
- PPIB | c.-14G>T | 5'UTR (SNP) | VAF 46/257 reads (18%) | catalogued as rs909568912; called by muse, mutect2, varscan2
- PPP2R2B | c.-108A>T | 5'UTR (SNP) | VAF 69/207 reads (33%) | called by muse, mutect2, varscan2
- PRSS40A | n.317+69G>T | Intron (SNP) | VAF 46/286 reads (16%) | called by muse, varscan2
- RNF170 | c.*2697G>A | 3'UTR (SNP) | VAF 30/185 reads (16%) | called by muse, varscan2
- RNF217-AS1 | n.1799G>T | RNA (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- RPL13A | chr19:49487564 G>T | 5'Flank (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- SAMD14 | c.823-67C>G | Intron (SNP) | VAF 43/372 reads (12%) | called by muse, mutect2, varscan2
- SEMA4C | c.-1C>A | 5'UTR (SNP) | VAF 123/450 reads (27%) | called by muse, mutect2, varscan2
- SERPINA13P | n.636T>C | RNA (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*2G>T | 3'UTR (SNP) | VAF 69/272 reads (25%) | called by muse, mutect2, varscan2
- SNORD114-15 | n.13G>A | RNA (SNP) | VAF 56/296 reads (19%) | called by muse, mutect2, varscan2
- SRGAP3 | c.1436+9G>T | Intron (SNP) | VAF 58/407 reads (14%) | called by muse, mutect2, varscan2
- TEX35 | c.543+31G>T | Intron (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2
- TJP1 | c.5152+48G>T | Intron (SNP) | VAF 9/69 reads (13%) | called by mutect2, varscan2
- TTK | c.2050-9G>T | Intron (SNP) | VAF 46/192 reads (24%) | called by muse, varscan2
- VIPR2 | c.51+248C>A | Intron (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5556C>A | Intron (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- ZNF230 | c.*1006C>G | 3'UTR (SNP) | VAF 17/93 reads (18%) | catalogued as rs1223066303; called by muse, mutect2, varscan2
- ZNF575 | c.135+602C>T | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as rs772830205; called by mutect2, varscan2
- ZNF578 | chr19:52451210 G>T | 5'Flank (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
